Somatic mutation profile of tumor specimen TCGA-BB-8601-01A (aliquot TCGA-BB-8601-01A-11D-2394-08) from TCGA case TCGA-BB-8601, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.1 years (30,721 days).
Specimen TCGA-BB-8601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edfb308d-17a3-4689-a88f-725af30a8c33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-8601-10A (Blood Derived Normal), aliquot TCGA-BB-8601-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07b5538a-308b-467f-b548-d38262c6066a

The open-access MAF lists 77 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 21, Nonsense Mutation 5, Intron 2, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.983dup p.T329Hfs*8 | Frame Shift Ins (INS) | VAF 39/72 reads (54%) | catalogued as rs886041285, COSV52927593; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.2123A>G p.Q708R | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV57055112; called by muse, mutect2, varscan2
- ADAMTS14 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.959); catalogued as rs766375814, COSV64603147, COSV99059316; called by muse, mutect2, varscan2
- ADAP1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs373846581; called by muse, mutect2, varscan2
- ADGRE1 | c.514+1G>T p.X172_splice | Splice Site (SNP) | VAF 39/79 reads (49%) | catalogued as COSV99165280; called by muse, mutect2, varscan2
- AMD1 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.709); catalogued as rs201905478, COSV100924490; called by muse, mutect2, varscan2
- ASH1L | c.2771C>G p.S924C | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV64206261; called by muse, mutect2, varscan2
- CDCA4 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV100288204; called by muse, mutect2, varscan2
- CNTN6 | c.203A>T p.D68V | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV100610730; called by muse, varscan2
- CUL3 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159640544, COSV52365892; called by muse, mutect2, varscan2
- CYFIP2 | c.2119A>T p.K707* (on ENST00000616178 / NM_001291722.2; = p.K682* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 90/124 reads (73%) | catalogued as COSV100556900; called by muse, mutect2, varscan2
- CYP7A1 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 104/243 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs886353028, COSV100052369; called by muse, mutect2, varscan2
- ELP4 | c.233T>A p.L78* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV63353715; called by muse, mutect2, varscan2
- EXOC4 | c.1984A>G p.K662E | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV54103057; called by muse, mutect2, varscan2
- FARS2 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51166002, COSV51169053; called by muse, mutect2, varscan2
- GLB1L3 | c.505A>G p.M169V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101111063; called by muse, varscan2
- HCN1 | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs146123836; called by muse, mutect2, varscan2
- HHIP | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV56840466; called by muse, mutect2, varscan2
- IPO7 | c.1925C>T p.T642I | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100797817; called by muse, mutect2, varscan2
- JAK3 | c.1150T>A p.F384I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV71686214; called by muse, mutect2, varscan2
- KCNB2 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV101578785; called by muse, mutect2, varscan2
- KIAA1217 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.294); catalogued as COSV100286644; called by muse, mutect2, varscan2
- KMT2A | c.7322A>G p.H2441R | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1555046515, COSV100628844; called by muse, mutect2, varscan2
- LPAR1 | c.478A>G p.S160G | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100730826, COSV62691863; called by muse, mutect2, varscan2
- LTBP1 | c.4613G>A p.R1538Q (on ENST00000404816 / NM_206943.4; = p.R1212Q on NM_000627.4) | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.26); catalogued as rs746736222, COSV99698285; called by muse, mutect2, varscan2
- MEIOC | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs376006001; called by muse, mutect2, varscan2
- MFHAS1 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs765592110, COSV99359190; called by muse, mutect2, varscan2
- MYO1H | c.2261A>G p.Q754R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1293091529, COSV100183548; called by muse, mutect2, varscan2
- NID1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99937502; called by muse, mutect2
- NOX5 | c.2120C>T p.T707M | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs770046307, COSV99533050; called by muse, mutect2, varscan2
- NOXRED1 | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771873920, COSV100033092; called by muse, varscan2
- OR4E2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs369264275; called by muse, mutect2, varscan2
- PHC3 | c.2206C>G p.L736V (on ENST00000494943 / NM_001308116.2; = p.L748V on NM_024947.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV101520160; called by muse, mutect2, varscan2
- RASA1 | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 64/86 reads (74%) | catalogued as COSV57193439; called by muse, mutect2, varscan2
- RELN | c.8035G>C p.V2679L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59008975; called by muse, mutect2, varscan2
- RNPEP | c.1635A>T p.K545N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV55241746; called by muse, mutect2, varscan2
- SLC14A2 | c.2630A>T p.N877I | Missense Mutation (SNP) | VAF 171/247 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV54910119; called by muse, mutect2
- SLC25A6 | c.718A>T p.M240L | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs755639289, COSV100452281; called by muse, mutect2, varscan2
- SLC35F5 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99830051; called by muse, mutect2, varscan2
- STX19 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV100115455; called by muse, mutect2, varscan2
- STYK1 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99311896; called by muse, mutect2, varscan2
- SYNE3 | c.782C>A p.T261K | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV100516001; called by muse, mutect2, varscan2
- SYNPO2 | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100205574, COSV100206212; called by muse, mutect2, varscan2
- TEX15 | c.3323G>T p.S1108I (on ENST00000256246; = p.S1491I on NM_001350162.2) | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs940250393, COSV56347781; called by muse, mutect2, varscan2
- TMEM123 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV100772264; called by muse, mutect2, varscan2
- TNXB | c.2096G>T p.R699L | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV64479025; called by muse, mutect2, varscan2
- TRAPPC9 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761866619, COSV101227452; called by muse, mutect2, varscan2
- UBR2 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100867446; called by muse, mutect2, varscan2
- ANGPT1 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CELSR3 | c.1787_1790del p.D596Afs*94 | Frame Shift Del (DEL) | VAF 21/34 reads (62%) | called by mutect2, pindel, varscan2
- FBXW7 | c.983dup p.I330Dfs*2 (on ENST00000281708 / NM_001349798.2; = p.I250Dfs*2 on NM_018315.5) | Frame Shift Ins (INS) | VAF 22/39 reads (56%) | called by mutect2, pindel, varscan2
- LIMK2 | c.1129del p.X377_splice | Splice Site (DEL) | VAF 42/130 reads (32%) | called by mutect2, pindel, varscan2
- RBMS2 | c.797dup p.Y266* | Nonsense Mutation (INS) | VAF 45/203 reads (22%) | called by mutect2, pindel, varscan2
- SSTR2 | c.321del p.W108Gfs*12 | Frame Shift Del (DEL) | VAF 50/148 reads (34%) | called by mutect2, pindel, varscan2
- AC092143.1 | c.1899G>A p.V633= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as COSV100205800; called by muse, mutect2
- ADAMTS17 | c.999G>T p.P333= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV51491873, COSV99170690; called by muse, mutect2
- ADGRL4 | c.1105C>T p.L369= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as rs749257756, COSV100875957; called by muse, mutect2, varscan2
- CCR4 | c.643T>C p.L215= | Silent (SNP) | VAF 97/120 reads (81%) | catalogued as COSV100447404; called by muse, mutect2, varscan2
- CLVS1 | c.408C>T p.Y136= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs758197932, COSV57981019, COSV57981660; called by muse, mutect2, varscan2
- CRAMP1 | c.3216C>A p.V1072= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99246018; called by muse, mutect2, varscan2
- EIF4G1 | c.4572G>T p.A1524= (on ENST00000346169 / NM_198241.3; = p.A1329= on NM_004953.5) | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV100071794, COSV59992050; called by muse, mutect2, varscan2
- EXOC7 | c.261C>A p.V87= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as rs1158518098, COSV100135284; called by muse, mutect2, varscan2
- GPC5 | c.1500T>C p.D500= | Silent (SNP) | VAF 71/91 reads (78%) | catalogued as COSV100993985; called by muse, mutect2, varscan2
- HOMER3 | c.96G>A p.K32= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99651100; called by muse, mutect2, varscan2
- KCNH3 | c.1209C>T p.A403= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99235232; called by muse, mutect2
- L3MBTL3 | c.1674C>T p.C558= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100696158; called by muse, mutect2, varscan2
- LRP4 | c.3783C>T p.L1261= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs1221882082, COSV101066616; called by muse, mutect2, varscan2
- MNS1 | c.255C>A p.L85= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99549604; called by muse, mutect2, varscan2
- NMD3 | c.150C>T p.V50= | Silent (SNP) | VAF 66/207 reads (32%) | catalogued as rs1326934820, COSV100664697; called by muse, mutect2, varscan2
- NME1 | c.198A>G p.K66= | Silent (SNP) | VAF 75/186 reads (40%) | catalogued as COSV99184026; called by muse, mutect2, varscan2
- OR3A2 | c.18C>T p.L6= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as rs576062413, COSV101375055; called by muse, mutect2
- POLQ | c.4920A>T p.P1640= | Silent (SNP) | VAF 80/410 reads (20%) | catalogued as COSV99952264; called by muse, mutect2, varscan2
- PPP2R2D | c.939G>A p.S313= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as rs781981250, COSV70778780; called by muse, mutect2, varscan2
- RASAL1 | c.366G>T p.L122= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as COSV99921724; called by muse, mutect2, varscan2
- ZNF479 | c.190T>C p.L64= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as COSV58642519; called by muse, mutect2, varscan2
- RPS8 | c.112-98A>G | Intron (SNP) | VAF 72/86 reads (84%) | catalogued as COSV100785476; called by muse, mutect2, varscan2
- ZNF783 | c.802+3223C>A | Intron (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100954247; called by muse, varscan2
